Somatic mutation profile of tumor specimen TCGA-FX-A2QS-01A (aliquot TCGA-FX-A2QS-01A-11D-A21Q-09) from TCGA case TCGA-FX-A2QS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 61.4 years (22,422 days).
Specimen TCGA-FX-A2QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46a179a4-a57c-427f-82dd-dc91b865dcc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A2QS-10A (Blood Derived Normal), aliquot TCGA-FX-A2QS-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4598cbe6-e8aa-4ef5-b792-79ece2483d35

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs201568572; called by muse, mutect2, varscan2
- CLDN6 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1455379665, COSV58511108; called by muse, mutect2, varscan2
- CPNE6 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99393176; called by muse, mutect2, varscan2
- DBF4 | c.358C>G p.H120D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs1562758129; called by muse, mutect2, varscan2
- DIS3L | c.310C>T p.R104* (on ENST00000319212 / NM_001143688.3; = p.R21* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs755849191; called by muse, mutect2, varscan2
- DSCAM | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.867); catalogued as rs760422019; called by muse, mutect2, varscan2
- EBAG9 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100520772; called by muse, mutect2
- FCHO1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs767793852; called by muse, mutect2, varscan2
- FLG | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.671); catalogued as COSV100910287, COSV64235705; called by muse, mutect2
- KRT79 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs921269254, COSV57940406, COSV57942467; called by muse, mutect2, varscan2
- LILRB5 | c.1405G>A p.V469I (on ENST00000449561 / NM_001081442.3; = p.V468I on NM_006840.5) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs146369950; called by muse, mutect2, varscan2
- MARCHF9 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 36/810 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99874960; called by muse, mutect2
- METRN | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs771353079, COSV101623095; called by muse, mutect2, varscan2
- MROH2B | c.4589C>A p.A1530D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as COSV68190099; called by muse, mutect2, varscan2
- MUC16 | c.33121G>T p.V11041L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV101199236; called by muse, mutect2, varscan2
- MUC3A | c.7031C>T p.S2344L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); catalogued as rs779034557; called by muse, mutect2, varscan2
- MYF5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408823197, COSV99953427; called by muse, mutect2, varscan2
- MYO7B | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV67344204; called by muse, mutect2, varscan2
- OR11H12 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 188/236 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101612463; called by muse, varscan2
- PRDM2 | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV52455130; called by muse, mutect2
- SLC44A2 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs980774061; called by muse, mutect2
- SRGAP3 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs547978979; called by muse, mutect2, varscan2
- TMEM217 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100362481; called by muse, mutect2
- TTN | c.16005C>G p.Y5335* (on ENST00000591111; = p.Y4408* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100605301; called by muse, mutect2, varscan2
- AL358113.1 | c.3806dup p.E1270* | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- ANO3 | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.2167del p.H723Mfs*33 | Frame Shift Del (DEL) | VAF 47/169 reads (28%) | called by mutect2, pindel, varscan2
- CEP350 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP2C18 | c.1459T>G p.F487V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- FOXI1 | c.4A>C p.S2R | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- GBP5 | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KIAA1217 | c.2362G>C p.E788Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF2B | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LGALS3BP | c.630_633dup p.F212Vfs*8 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- MRC1 | c.1144A>G p.K382E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); called by muse, mutect2
- NRSN1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2
- OSBPL6 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM2 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRBV3-1 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TRIM29 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TTN | c.67626G>T p.K22542N (on ENST00000591111; = p.K15118N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UMODL1 | c.3893T>A p.M1298K (on ENST00000408910 / NM_001004416.2; = p.M1426K on NM_173568.3) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13C | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WIPI2 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF25 | c.867C>T p.I289= | Silent (SNP) | VAF 24/279 reads (9%) | called by muse, mutect2
- CSTL1 | c.204T>A p.I68= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- LILRB5 | c.360C>T p.F120= | Silent (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- LRP1 | c.11823C>T p.H3941= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54513400; called by muse, mutect2, varscan2
- MYO5B | c.1074A>G p.L358= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs548182150; called by muse, mutect2, varscan2
- NID1 | c.3546G>A p.K1182= | Silent (SNP) | VAF 78/175 reads (45%) | called by muse, mutect2, varscan2
- NOS1 | c.1803C>T p.R601= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs371959195; called by muse, mutect2, varscan2
- PSD | c.978C>A p.G326= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- RYR1 | c.14796C>T p.I4932= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs1224746338; called by muse, mutect2, varscan2
- S1PR1 | c.63C>T p.N21= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59512956; called by muse, mutect2, varscan2
- SPEG | c.8124G>A p.T2708= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs374304716; called by muse, mutect2, varscan2
- VPS4B | c.441A>G p.K147= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- ARPC3 | c.-1G>T | 5'UTR (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99959476; called by muse, mutect2, varscan2
- CTSL3P | n.591C>G | RNA (SNP) | VAF 25/97 reads (26%) | catalogued as rs139706141; called by muse, mutect2, varscan2
